Surgical pathology report (de-identified scan), TCGA case TCGA-DH-A7US, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site University of Florida, specimen TCGA-DH-A7US-01A (Primary Tumor).

[page 1 of 3]
ICD-O-3
Oligodendroglioma, grade II
9450/3
Site: ^{CKF} Brain, supratentorial ^{NOS}
C71.0
4Bth
Overlapping lesion, glioma
C71.8
QW 10/4/13

Case Type:

SPECIMEN(S) SUBMITTED / PROCEDURES ORDERED

- A. Brain tumor A. Frozen Section Charge
B. Brain tumor B. Glial Fibrill. Acid Prt
B. Ki-67, Nuclear Antigen, Mib1 B. P53 Protein
B. Isocitrate dehydrogenase 1 B. 1P19q Malignant Glioma Anaysis
B. 1P19q Malignant Glioma Analysis, add x 3

CLINICAL HISTORY: A old male who presents for right crani for
tumor. Right frontal temporal insular lesion

DIAGNOSIS:

- A. "Brain tumor", frontotemporal lobe, craniotomy:
Oligodendroglioma, WHO Grade II (see comment)
B. "Brain tumor", frontotemporal lobe, craniotomy:
Oligodendroglioma, WHO Grade II (see comment)

COMMENT: Sections show an infiltrating tumor with predominantly
monomorphic ovoid nuclei with perinuclear halos and "chicken wire"
vasculature. No necrosis or microvascular proliferation is seen in this
material. Mitoses are not identified in the sections examined and the
Ki-67 (MIB-1) proliferation index is variable ranging from 1-7%
approximately. Immunohistochemical study for GFAP shows positive

[page 2 of 3]
reactivity in tumor cell processes. Tumor cells are strongly and diffusely positive for IDH1. P53 is negative in the majority of tumor cells. The histologic and immunohistochemical findings of this tumor support the diagnosis.

A 1p/19q chromosomal status analysis will be performed and results reported in an addendum.

GROSS DESCRIPTION: Received the following specimens in the _____
labeled with the patient's name and hospital #

A. Brain tumor

B. Brain tumor

A. The specimen is received fresh, designated "Brain tumor" and consists of a 2.5 x 2.0 x 1.5 cm aggregate of beige to pink-tan soft tissue pieces. A representative portion is submitted for frozen section. Frozen section diagnosis is "Infiltrating glioma, defer grade to permanent sections". The frozen tissue is submitted in cassette FSA1 and remaining tissue is submitted in cassettes A2 and A3.

B. The specimen is received fresh, designated "Brain tumor" and consists of a 1.8 x 1.5 x 1.0 cm aggregate of beige to gray-tan soft tissue with focal areas of hemorrhage. A representative portion is submitted to the _____ and remaining tissue is submitted in cassettes B1-B3.

"I, or my qualified designee, performed the gross examination. I have personally reviewed the gross description and performed a microscopic examination on all referenced material. I have personally issued this report on the basis of the gross and microscopic findings."

[page 3 of 3]
Note: Test systems have been developed and their performance characteristics determined by Some tests have not been cleared or approved by the U.S. Food and Drug Administration. The FDA has determined that such clearance is not necessary. These tests are used for clinical purposes and should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA-88) as qualified to perform high complexity clinical laboratory testing.

Pathologist

Source: NCI Genomic Data Commons file cc720fc6-1e00-4742-8fd3-ab3a68976552 (TCGA-DH-A7US.1078C5C3-CA98-48D7-B810-162029AC4238.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).